TCGA case TCGA-WX-AA44 — Liver Hepatocellular Carcinoma (TCGA-LIHC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Liver and intrahepatic bile ducts; Tissue source site: Yale University. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5436fafb-bc16-4450-ac8b-568e1e5ee5fe

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Country of residence at enrollment: United States; Age at index: 64 years; Vital status: Alive.

Diagnoses (2)
1. Hepatocellular carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8170/3; ICD-10 code: C22.0; Tissue or organ of origin: Liver; Site of resection or biopsy: Liver; Classification of tumor: primary; Age at diagnosis: 64.8 years (23,654 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T1; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage I; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: RX; Child pugh classification: A; Ishak fibrosis score: 6 - Established Cirrhosis.
   Pathology details: Consistent pathology review: Yes; Vascular invasion present: No.
   Treatment given: Treatment type: Radioembolization; Days to treatment start: 274 days; Embolic agent: Y-90 Sirsphere.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Sorafenib; Days to treatment start: 306 days; Days to treatment end: 375 days (1.0 years); Treatment outcome: Partial Response.
   Treatment given: Treatment type: Radiation, Internal; Days to treatment start: 357 days; Days to treatment end: 357 days; Treatment outcome: Partial Response; Number of fractions: 1; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis.
2. Recurrence of diagnosis 1 (Hepatocellular carcinoma, NOS), site: Liver. Age at diagnosis: 65.4 years (23,900 days); Days to diagnosis: 246 days; Prior treatment: Yes.
   Treatment given: Treatment type: Ablation or Embolization, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Organ Transplantation to Liver, for recurrent disease.

Follow-up (4 entries)
- Day 246 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Local; Progression or recurrence anatomic site: Liver; Days to recurrence: 246 days.
- Days to follow up: 473 days (1.3 years); Disease response: With Tumor.
- Days to follow up: 615 days (1.7 years); Disease response: With Tumor.
- ECOG performance status: 1.

Molecular and laboratory tests
- Total Bilirubin 0.5 mg/dL [Blood test normal range lower: 0; Blood test normal range upper: 1.2].
- Platelets 215 (unit not recorded by GDC) [Blood test normal range lower: 150; Blood test normal range upper: 350].
- Albumin 4.4 (unit not recorded on the TCGA source form) [Blood test normal range lower: 3.5; Blood test normal range upper: 5].
- Alpha Fetoprotein 48 ng/mL [Blood test normal range lower: 0; Blood test normal range upper: 6].
- Prothrombin time (INR, as labelled on the TCGA clinical form) 0.9 [Blood test normal range lower: 0.9; Blood test normal range upper: 1.2].
- Creatinine 0.6 mg/dL [Blood test normal range lower: 0.5; Blood test normal range upper: 1.2].

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 61 kg; Height: 152 cm; BMI: 26.4.
- Timepoint category: Prior to Diagnosis; Risk factors: Nonalcoholic Fatty Liver Disease; Viral hepatitis serology tests: Hepatitis C Antibody.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-WX-AA44-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 90 mg.
  Slide TCGA-WX-AA44-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-WX-AA44-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-WX-AA44-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: With tumor; Histologic diagnosis: Hepatocellular Carcinoma; Surgical procedure other: Left lateral hepatectomy.
- Viral hepatitis serologies: Viral hepatitis serology: Hepatitis  C Antibody.
- Follow-up form: Lost to follow-up: Yes; Tumor status: With tumor.
- Ablations, Ablation, Ablation treatments: Ablation performed indicator: No.
- Ablations, Ablation, Embolization treatments: Embolization performed indicator: Yes.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 615 days; disease-specific survival: no event (censored), 615 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 246 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-WX-AA44-01A-11D-A38W-01): tumor purity 0.64, ploidy 2.18, whole-genome doublings 0.
